Somatic mutation profile of tumor specimen C3L-04767-54 (aliquot CPT0260760002) from CPTAC case C3L-04767, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 58.5 years (21,368 days).
Specimen C3L-04767-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90b46383-2909-40d4-ba36-468f6743db90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04767-51 (Buccal Cell Normal), aliquot CPT0260750003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2c206b0-b73f-4ad0-910b-b83cdb3b2780

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Ins 2, 5'UTR 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 78/490 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- SETBP1 | c.2608G>A p.G870S | Missense Mutation (SNP) | VAF 131/325 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267607040, CM103049, CM148164, COSV56311834, COSV56315308; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.2757dup p.P920Tfs*4 | Frame Shift Ins (INS) | VAF 162/448 reads (36%) | catalogued as rs771822198, CI127605; called by mutect2, varscan2
- CTSE | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as rs141663034; called by muse, mutect2, varscan2
- KIAA1210 | c.3886C>G p.Q1296E | Missense Mutation (SNP) | VAF 83/208 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV68175741; called by muse, mutect2, varscan2
- PRPF8 | c.4781G>A p.C1594Y | Missense Mutation (SNP) | VAF 141/365 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs770896496, COSV59261386; called by muse, mutect2, varscan2
- SRRM2 | c.5831G>A p.R1944H | Missense Mutation (SNP) | VAF 17/404 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1291215133, COSV57077045; called by muse, mutect2
- TUFM | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 204/449 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs377591597, COSV57948691; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDHA7 | c.582dup p.V195Cfs*43 | Frame Shift Ins (INS) | VAF 58/129 reads (45%) | called by mutect2, varscan2
- RUNX1 | c.883_884del p.S295Nfs*277 (on ENST00000344691 / NM_001001890.3; = p.S322Nfs*277 on NM_001754.5) | Frame Shift Del (DEL) | VAF 104/320 reads (33%) | called by pindel, varscan2
- ATP13A3 | c.3225A>G p.T1075= | Silent (SNP) | VAF 75/171 reads (44%) | called by muse, mutect2, varscan2
- FOXD4L4 | c.627G>A p.L209= | Silent (SNP) | VAF 37/254 reads (15%) | called by mutect2, varscan2
- FOXD4L5 | c.627G>A p.L209= | Silent (SNP) | VAF 12/45 reads (27%) | called by mutect2, varscan2
- PKD1L3 | c.4164C>T p.N1388= | Silent (SNP) | VAF 180/372 reads (48%) | catalogued as rs776559251; called by muse, mutect2, varscan2
- CABP5 | c.-2C>A | 5'UTR (SNP) | VAF 11/34 reads (32%) | called by muse, varscan2
- POLR2F | c.453-14979C>T | Intron (SNP) | VAF 59/258 reads (23%) | called by muse, mutect2, varscan2
